Somatic mutation profile of tumor specimen fe83e13f-9754-403b-8f74-d6caf8 (aliquot fe83e13f-9754-403b-8f74-d6caf8_D6) from CPTAC case 04OV021, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC.
Specimen fe83e13f-9754-403b-8f74-d6caf8: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 82d047d1-38d3-4dde-8a93-ffac922c4b34.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 67f382d0-dd95-4c54-8123-246343 (Blood Derived Normal), aliquot 67f382d0-dd95-4c54-8123-246343_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8a16dd52-3d7e-4410-95e4-8d9a6582fd49

The open-access MAF lists 126 somatic variants for this specimen: 88 protein-altering or splice-affecting, 23 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 23, Intron 12, Nonsense Mutation 10, In Frame Del 2, Splice Site 2, RNA 1, 5'UTR 1, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.796G>A p.G266R | Missense Mutation (SNP) | VAF 201/382 reads (53%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as rs1057519990, COSV52670619, COSV52672762, COSV52751844; ClinVar: pathogenic / likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ADNP | c.1228C>G p.P410A | Missense Mutation (SNP) | VAF 30/391 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100823728; called by muse, mutect2
- ANKS6 | c.2249C>A p.S750Y | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV62050939; called by muse, mutect2, varscan2
- APOB | c.9597G>C p.Q3199H | Missense Mutation (SNP) | VAF 29/276 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.019); catalogued as COSV51942637; called by muse, mutect2, varscan2
- ARHGEF4 | c.1612C>T p.R538C | Missense Mutation (SNP) | VAF 34/305 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1233481709; called by muse, mutect2
- ATAD2B | c.509G>C p.R170P | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99478051; called by muse, mutect2, varscan2
- CALCR | c.376C>T p.R126* | Nonsense Mutation (SNP) | VAF 12/122 reads (10%) | catalogued as rs1046608937; called by muse, mutect2, varscan2
- CDH23 | c.6887T>A p.F2296Y | Missense Mutation (SNP) | VAF 54/255 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV99821726; called by mutect2, varscan2
- CEP104 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs150169294; called by muse, mutect2, varscan2
- CLEC14A | c.1454T>C p.L485P | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); catalogued as rs145550581; called by muse, mutect2, varscan2
- CTBP2 | c.82G>A p.G28S | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.056); catalogued as rs371796986; called by muse, mutect2, varscan2
- CTDSPL | c.793G>T p.D265Y (on ENST00000273179 / NM_001008392.2; = p.D254Y on NM_005808.3) | Missense Mutation (SNP) | VAF 29/189 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56201796; called by muse, mutect2, varscan2
- GART | c.2071C>G p.P691A | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.412); catalogued as COSV101111356; called by muse, mutect2, varscan2
- GPD1 | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1454527267; called by muse, mutect2
- GTPBP4 | c.47A>T p.K16M | Missense Mutation (SNP) | VAF 17/230 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as rs201885506; called by muse, mutect2
- HIVEP3 | c.4588G>A p.A1530T | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs1401580638; called by muse, mutect2, varscan2
- HOXB13 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 71/154 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV51706131; called by muse, mutect2, varscan2
- HOXC8 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 55/557 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs749816109, COSV50001325; called by muse, mutect2, varscan2
- KIAA1614 | c.1367C>A p.S456Y | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62551086; called by muse, mutect2, varscan2
- OOEP | c.199C>T p.R67* | Nonsense Mutation (SNP) | VAF 37/112 reads (33%) | catalogued as rs1054721483, COSV64859273; called by muse, mutect2, varscan2
- PITPNM2 | c.3079G>A p.G1027R | Missense Mutation (SNP) | VAF 47/305 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV99758467; called by muse, mutect2, varscan2
- POU3F4 | c.817G>A p.A273T | Missense Mutation (SNP) | VAF 58/246 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.339); catalogued as rs777196693; called by muse, mutect2, varscan2
- RUNX3 | c.776C>T p.T259M | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs756674957, COSV58244513; called by muse, mutect2, varscan2
- SCART1 | c.1172G>C p.W391S | Missense Mutation (SNP) | VAF 35/191 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV62986294; called by muse, mutect2, varscan2
- SCG2 | c.1315C>G p.L439V | Missense Mutation (SNP) | VAF 22/242 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.017); catalogued as COSV100544750; called by muse, mutect2
- SMARCC1 | c.1063C>T p.R355C | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as rs774816681; called by muse, mutect2, varscan2
- SUPT6H | c.1651C>G p.R551G | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV58930768; called by muse, mutect2, varscan2
- SYTL5 | c.1034G>A p.S345N | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as rs752315612; called by muse, mutect2, varscan2
- TBC1D4 | c.134G>T p.C45F | Missense Mutation (SNP) | VAF 4/57 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as rs1324083582; called by muse, mutect2
- UMOD | c.808G>C p.G270R | Missense Mutation (SNP) | VAF 66/316 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as CM088473, COSV56773969; called by muse, mutect2, varscan2
- WWP1 | c.2299C>G p.R767G | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55357038; called by muse, mutect2, varscan2
- ZCCHC8 | c.1226C>A p.A409E | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs201799696; called by muse, mutect2, varscan2
- ZFC3H1 | c.218C>T p.S73F | Missense Mutation (SNP) | VAF 52/435 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.075); catalogued as rs183795222, COSV57350218; called by muse, varscan2
- ZMYM2 | c.1815C>A p.Y605* | Nonsense Mutation (SNP) | VAF 23/101 reads (23%) | catalogued as COSV67032987; called by muse, mutect2, varscan2
- ABCA7 | c.555_566del p.E185_E188del | In Frame Del (DEL) | VAF 14/90 reads (16%) | called by mutect2, pindel, varscan2
- ACP4 | c.1276G>T p.V426L | Missense Mutation (SNP) | VAF 29/208 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- AKAP9 | c.7159T>A p.L2387M (on ENST00000359028; = p.L2363M on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/209 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ANO6 | c.2217+1G>A p.X739_splice | Splice Site (SNP) | VAF 42/344 reads (12%) | called by muse, mutect2, varscan2
- ATG9B | c.605A>G p.Y202C | Missense Mutation (SNP) | VAF 49/248 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- BAIAP3 | c.2645C>G p.P882R | Missense Mutation (SNP) | VAF 63/410 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CARD11 | c.1964C>T p.S655F | Missense Mutation (SNP) | VAF 10/161 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.741); called by muse, mutect2
- COL6A5 | c.1612G>T p.D538Y | Missense Mutation (SNP) | VAF 30/314 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.155); called by muse, mutect2
- CYP27A1 | c.784C>G p.R262G | Missense Mutation (SNP) | VAF 68/503 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- CYP4F12 | c.924A>T p.E308D | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- DDX49 | c.82G>A p.V28M | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DLK2 | c.490G>T p.V164L | Missense Mutation (SNP) | VAF 37/285 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DPY19L3 | c.1610A>C p.Y537S | Missense Mutation (SNP) | VAF 30/151 reads (20%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.501); called by muse, mutect2, varscan2
- EBLN1 | c.779A>G p.E260G | Missense Mutation (SNP) | VAF 62/344 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); called by muse, mutect2, varscan2
- EIF3I | c.860C>T p.P287L | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FBXL4 | c.1756G>T p.D586Y | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- FCAMR | c.86C>G p.A29G | Missense Mutation (SNP) | VAF 37/142 reads (26%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FCRL5 | c.2719G>T p.E907* | Nonsense Mutation (SNP) | VAF 28/118 reads (24%) | called by muse, mutect2, varscan2
- FUT6 | c.951C>A p.S317R | Missense Mutation (SNP) | VAF 210/782 reads (27%) | SIFT tolerated (0.77); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GOT1 | c.857C>G p.S286C | Missense Mutation (SNP) | VAF 66/179 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- GPR162 | c.1209C>A p.Y403* (on ENST00000311268 / NM_019858.2; = p.Y119* on NM_014449.2) | Nonsense Mutation (SNP) | VAF 13/108 reads (12%) | called by muse, mutect2, varscan2
- GPT | c.1256_1261del p.Q419_L420del | In Frame Del (DEL) | VAF 51/280 reads (18%) | called by pindel, varscan2*
- IGKV3-7 | c.159C>A p.Y53* | Nonsense Mutation (SNP) | VAF 61/571 reads (11%) | called by muse, mutect2, varscan2
- IGSF9B | c.1058C>T p.P353L | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- INPP1 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- ISYNA1 | c.416G>A p.G139D | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ISYNA1 | c.416-1G>C p.X139_splice | Splice Site (SNP) | VAF 10/103 reads (10%) | called by muse, mutect2
- KDM5C | c.754G>C p.A252P | Missense Mutation (SNP) | VAF 88/453 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- KIAA1671 | c.3821C>A p.P1274H | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2
- MUC4 | c.7628C>G p.T2543S | Missense Mutation (SNP) | VAF 66/600 reads (11%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.301); called by muse, varscan2
- NFYB | c.121G>A p.D41N | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- OTX1 | c.916G>T p.G306C | Missense Mutation (SNP) | VAF 33/302 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- PCDH15 | c.5162A>C p.D1721A | Missense Mutation (SNP) | VAF 65/402 reads (16%) | SIFT deleterious, low confidence (0.02); called by muse, mutect2, varscan2
- PLCH1 | c.3832A>G p.T1278A (on ENST00000340059 / NM_001130960.2; = p.T1270A on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/346 reads (13%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- PNMA2 | c.1033A>C p.S345R | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- POTEB3 | c.1189C>T p.Q397* | Nonsense Mutation (SNP) | VAF 11/117 reads (9%) | called by muse, mutect2
- PTPRN | c.2006C>A p.P669H | Missense Mutation (SNP) | VAF 54/360 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- RABEPK | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 65/118 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- RASA2 | c.355G>C p.G119R | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SCML4 | c.306G>C p.K102N | Missense Mutation (SNP) | VAF 81/260 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SFMBT2 | c.670G>T p.E224* | Nonsense Mutation (SNP) | VAF 27/277 reads (10%) | called by muse, mutect2, varscan2
- SLCO2B1 | c.509C>A p.S170* | Nonsense Mutation (SNP) | VAF 42/300 reads (14%) | called by muse, mutect2, varscan2
- SP110 | c.1250C>A p.T417N | Missense Mutation (SNP) | VAF 61/534 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- SPRING1 | c.607_608dup p.P204Sfs*19 | Frame Shift Ins (INS) | VAF 63/182 reads (35%) | called by mutect2, pindel, varscan2
- ST8SIA1 | c.1028A>T p.Q343L | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- STRIP2 | c.2208C>A p.Y736* | Nonsense Mutation (SNP) | VAF 29/195 reads (15%) | called by muse, mutect2, varscan2
- TAF4B | c.2033C>G p.S678C | Missense Mutation (SNP) | VAF 30/163 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TCN2 | c.1218G>C p.L406F | Missense Mutation (SNP) | VAF 101/242 reads (42%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- TMEM201 | c.340G>T p.V114L | Missense Mutation (SNP) | VAF 25/196 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TPR | c.2761C>A p.Q921K | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.97); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- TSHZ3 | c.1466A>T p.D489V | Missense Mutation (SNP) | VAF 66/1106 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2
- TTN | c.1393G>C p.E465Q | Missense Mutation (SNP) | VAF 51/441 reads (12%) | PolyPhen benign (0.093); called by muse, mutect2, varscan2
- ZNF219 | c.1276C>T p.P426S | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF471 | c.1318T>A p.F440I | Missense Mutation (SNP) | VAF 36/211 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CBX4 | c.174G>A p.Q58= | Silent (SNP) | VAF 73/217 reads (34%) | called by muse, mutect2, varscan2
- CEP250 | c.1402C>T p.L468= | Silent (SNP) | VAF 18/99 reads (18%) | called by muse, mutect2, varscan2
- CNTNAP3 | c.69G>T p.V23= | Silent (SNP) | VAF 14/58 reads (24%) | called by muse, mutect2, varscan2
- GCC2 | c.1260A>G p.E420= | Silent (SNP) | VAF 11/105 reads (10%) | called by muse, mutect2, varscan2
- KCNMB2 | c.390C>T p.Y130= | Silent (SNP) | VAF 16/124 reads (13%) | called by muse, mutect2, varscan2
- NEB | c.762G>A p.T254= | Silent (SNP) | VAF 30/169 reads (18%) | catalogued as rs770784055; ClinVar: likely benign; called by muse, mutect2, varscan2
- NEXMIF | c.1125G>A p.E375= | Silent (SNP) | VAF 160/279 reads (57%) | called by muse, mutect2, varscan2
- OR10W1 | c.99C>T p.N33= | Silent (SNP) | VAF 55/330 reads (17%) | catalogued as rs1247199571, COSV67720236; called by muse, mutect2, varscan2
- OR2AP1 | c.444G>T p.L148= | Silent (SNP) | VAF 50/479 reads (10%) | called by muse, mutect2, varscan2
- OR2T27 | c.462C>T p.I154= | Silent (SNP) | VAF 37/368 reads (10%) | catalogued as rs779753009; called by muse, mutect2
- PAPPA | c.3951T>G p.P1317= | Silent (SNP) | VAF 14/74 reads (19%) | called by muse, mutect2, varscan2
- PAPPA2 | c.1875T>C p.D625= | Silent (SNP) | VAF 44/353 reads (12%) | called by muse, mutect2, varscan2
- PROKR2 | c.588C>G p.V196= | Silent (SNP) | VAF 92/1032 reads (9%) | called by muse, mutect2
- RBM12B | c.1923G>A p.E641= | Silent (SNP) | VAF 38/264 reads (14%) | called by mutect2, varscan2
- SAMD9 | c.3261G>A p.A1087= | Silent (SNP) | VAF 51/361 reads (14%) | catalogued as rs372006940, COSV66075541; called by muse, mutect2, varscan2
- TRPM3 | c.2730A>T p.V910= (on ENST00000357533 / NM_001366142.2; = p.V753= on NM_020952.6) | Silent (SNP) | VAF 23/125 reads (18%) | catalogued as rs1411506327; called by muse, mutect2, varscan2
- TTBK1 | c.963G>C p.T321= | Silent (SNP) | VAF 19/165 reads (12%) | called by muse, mutect2, varscan2
- UBQLN4 | c.804C>G p.A268= | Silent (SNP) | VAF 20/184 reads (11%) | catalogued as COSV64149288, COSV64150510; called by mutect2, varscan2
- USP25 | c.2379A>G p.Q793= | Silent (SNP) | VAF 6/22 reads (27%) | called by muse, mutect2, varscan2
- USP34 | c.9915C>T p.P3305= | Silent (SNP) | VAF 29/128 reads (23%) | called by muse, mutect2, varscan2
- VIM | c.768C>T p.I256= | Silent (SNP) | VAF 64/487 reads (13%) | catalogued as rs377349430; called by muse, mutect2, varscan2
- WTAP | c.861G>C p.T287= | Silent (SNP) | VAF 46/270 reads (17%) | catalogued as rs149312050; called by muse, mutect2, varscan2
- ZMYM1 | c.1023G>A p.T341= | Silent (SNP) | VAF 16/109 reads (15%) | catalogued as rs546867983, COSV63250626; called by muse, mutect2, varscan2
- ADD2 | c.1742-252A>T | Intron (SNP) | VAF 14/131 reads (11%) | called by muse, mutect2, varscan2
- AZGP1P1 | n.343G>T | RNA (SNP) | VAF 32/178 reads (18%) | called by muse, mutect2, varscan2
- CAMK1 | c.912+344T>C | Intron (SNP) | VAF 26/321 reads (8%) | called by muse, mutect2
- CTSF | c.213+65A>G | Intron (SNP) | VAF 23/77 reads (30%) | catalogued as rs1455574994; called by muse, mutect2, varscan2
- DKK3 | c.435+32C>T | Intron (SNP) | VAF 26/149 reads (17%) | catalogued as rs748537627; called by muse, mutect2, varscan2
- DPM2 | c.3+22G>T | Intron (SNP) | VAF 18/105 reads (17%) | called by muse, mutect2, varscan2
- ELP1 | c.3223-9C>T | Intron (SNP) | VAF 33/299 reads (11%) | catalogued as rs777231662; called by muse, mutect2, varscan2
- EML2 | chr19:45641733 G>C | 5'Flank (SNP) | VAF 17/124 reads (14%) | called by muse, mutect2, varscan2
- MPRIP | c.2164-5123C>T | Intron (SNP) | VAF 26/245 reads (11%) | called by muse, mutect2
- NDUFAF6 | c.298-1441C>T | Intron (SNP) | VAF 30/107 reads (28%) | called by muse, mutect2, varscan2
- RAB2A | c.-46C>T | 5'UTR (SNP) | VAF 14/34 reads (41%) | called by muse, mutect2, varscan2
- RCN2 | c.447+3058A>G | Intron (SNP) | VAF 35/151 reads (23%) | called by muse, mutect2, varscan2
- RPS2 | c.375+48C>G | Intron (SNP) | VAF 137/307 reads (45%) | catalogued as rs765852789, COSV99238755; called by muse, mutect2, varscan2
- TNFRSF14 | c.305-447C>A | Intron (SNP) | VAF 60/345 reads (17%) | called by muse, mutect2, varscan2
- ZNF497 | c.-111-845G>A | Intron (SNP) | VAF 35/283 reads (12%) | called by muse, mutect2, varscan2
